CCDI case PBBSED — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/6f807c20-123b-4ad3-bef1-86a876c1ebea

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Leiomyosarcoma, NOS: ICD-O-3 morphology code: 8890/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 7.2 years (2,640 days).

Biospecimens (3 samples)
- Sample 0DFO13: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFO18: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DG9M9: Tissue type: Tumor; Specimen type: Solid Tissue.
